CCDI case PBBWPX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/47dedb76-9e5a-4e4f-8090-c111cb640d4c

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 17.8 years (6,517 days).

Biospecimens (3 samples)
- Sample 0DJHE1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJHEH: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJHH7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
